Somatic mutation profile of tumor specimen 0DPEA1 from CCDI case PBCDLB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,971 days).
Specimen 0DPEA1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0008cff0-68e0-477b-b826-06fbd566db35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE96 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfb8889e-c5cf-4024-af35-c72f6c9bc50a

The open-access MAF lists 12 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 3, 5'UTR 2, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.3786T>G p.C1262W | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRACR2A | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 58/750 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 42/1262 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- HIPK2 | c.1032C>A p.V344= | Silent (SNP) | VAF 101/1145 reads (9%) | called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- ARHGEF12 | c.3532+91T>C | Intron (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- ARHGEF12 | c.3532+92G>A | Intron (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 28/566 reads (5%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 13/169 reads (8%) | called by muse, mutect2
- MEIOC | c.2457+94C>G | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 35/327 reads (11%) | catalogued as rs926414386, COSV100695372; called by muse, mutect2, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 35/315 reads (11%) | called by muse, mutect2, varscan2
